Surgical pathology report (de-identified scan), TCGA case TCGA-5A-A8ZF, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Wake Forest University, specimen TCGA-5A-A8ZF-01A (Primary Tumor).

[page 1 of 3]
ACCESSION NUMBER:
RECEIVED:
ORDERING PHYSICIAN:
PATIENT NAME:
SURGICAL PATHOLOGY REPORT

ICDO-3
Cholangiocarcinoma 8160/3
Intrahepatic bile duct C22.1
JW 1/21/14

FINAL PATHOLOGIC DIAGNOSIS
MICROSCOPIC EXAMINATION AND DIAGNOSIS

A. LIVER, RIGHT LOBE, SEGMENT 4-8, EXCISION:
Cholangiocarcinoma.

- Tumor focality: Unifocal.
- Tumor size: 7.5 cm (greatest gross dimension).
- Histologic grade: Moderately to poorly differentiated (grade 3).
- Microscopic tumor extension: Carcinoma invades liver parenchyma, extends into perihepatic fat, and invades the wall of the necrotic gallbladder.
- Perineural invasion: Present.
- Vascular invasion: Present (invades into a small muscular artery).
- Margins status: Negative for carcinoma.
- Closest approach: Less than 1 millimeter from the perihepatic adipose tissue margin.
- Local lymph nodes: Seven lymph nodes; negative for carcinoma (0/7).

B. PORTAL LYMPH NODES, EXCISION:
Five lymph nodes; negative for carcinoma (0/5).

Pathologic stage: pT3 pN0

INTRAHEPATIC BILE DUCTS RESECTION

SPECIMEN: Liver

Gallbladder

PROCEDURE: Partial hepatectomy

TUMOR SIZE: Greatest dimension: 7.5 cm

TUMOR FOCALITY: Solitary (location): Liver

HISTOLOGIC TYPE: Cholangiocarcinoma

HISTOLOGIC GRADE: GIII

TUMOR GROWTH PATTERN: Mass-forming

MICROSCOPIC TUMOR EXTENSION: Tumor directly invades gallbladder

[page 2 of 3]
MARGINS:

HEPATIC PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

BILE DUCT MARGIN: Uninvolved by invasive carcinoma

OTHER MARGIN: Not Applicable

LYMPH-VASCULAR INVASION: Macroscopic Venous (Large Vessel)

Invasion (V)-Not identified

Microscopic (Small Vessel) Invasion (L)-Present

PERINEURAL INVASION: Present

PATHOLOGIC STAGING (pTNM)

PRIMARY TUMOR (pT): pT3

REGIONAL LYMPH NODES (pN): pN0

DISTANT METASTASIS (pM): Not applicable

Report Prepared By: _____, Resident-Pathology

I have personally reviewed the slides and/or other related materials referenced, and have edited the report as part of my pathologic assessment and final interpretation.

Electronically Signed Out By:

Specimen(s) Received

A: Standard right lobe segment 4-8 of liver

B: Portal lymph node

Clinical History

{Not Provided}

Gross Description

A. Received labeled "standard right lobe segment 4-8 of liver" is a 182 g, 20.0 x 12.0 x 8.0 cm partial hepatectomy. The capsular surface is red to purple smooth and is distorted by an intraparenchymal mass. The resection margin is marked by black ink. Attached to the specimen is a 7.5 x 2.5 x 2.0 cm gallbladder. The serosal surface of the gallbladder is pale tan and is covered by a red-tan adhesion. The gallbladder is adhered

[page 3 of 3]
to the wall of the liver. The cystic duct margin is marked by black ink. The gallbladder is serially sectioned to reveal multiple white translucent, smooth, multifaceted stones ranging from 0.3 cm up to 1.5 cm within the lumen of the gallbladder. The specimen is serially sectioned to reveal a well-defined white tan mass, 7.5 x 5.5 x 5.5 cm. The mass extends to involve the wall of the gallbladder. The cut surface of the mass shows areas of necrosis and cystic degeneration. The mucosa of the gallbladder is tan-white and smooth with the proximal portion showing gross involvement by tumor. Representative sections are submitted to tissue procurement laboratory.

- A1 Cystic duct margin en face
- A2-4 Tumor in relation to the gallbladder wall
- A5-6 Tumor in relation to the liver margin of resection
- A7 Tumor in relation to the liver capsule
- A8-9 Tumor in relation to the uninvolved liver parenchyma
- A10 Uninvolved liver parenchyma

B. Received labeled "portal lymph node" are 2 red tan irregular fragments of soft tissue, 4.7 x 3.0 x 1.4 cm in aggregate. The specimen is bisected to reveal ranging from 0.5 cm up to 3.0 cm. Lymph nodes are submitted as follows;

- B1 5 lymph node candidates
- B2-3 One lymph node candidate in each cassette
- B4-6 One lymph node candidate

Source: NCI Genomic Data Commons file d71401fe-b2dd-40e9-9d21-9da2cf13ac26 (TCGA-5A-A8ZF.AE57B0FD-BB4D-482B-8DC9-23690AB56CB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).